Somatic mutation profile of tumor specimen C3N-00244-01 (aliquot CPT0014370007) from CPTAC case C3N-00244, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.2 years (16,873 days).
Specimen C3N-00244-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f446f9f2-d9d3-4048-954b-e33d34e72455.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00244-31 (Blood Derived Normal), aliquot CPT0015060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5849079-9c13-421b-94e1-b32ba9fe89dd

The open-access MAF lists 69 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 12, Intron 6, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.2474C>T p.T825M (on ENST00000506720 / NM_001322402.2; = p.T757M on NM_015236.6) | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746668174, COSV72229218; called by muse, mutect2, varscan2
- DGKA | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV59384837; called by muse, mutect2, varscan2
- EBF1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.389); catalogued as rs560006074; called by muse, mutect2, varscan2
- ERAL1 | c.424T>C p.S142P | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772772053; called by muse, mutect2, varscan2
- FREM2 | c.7900G>T p.A2634S | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as rs750989546; called by muse, mutect2, varscan2
- NFIX | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1204135009, COSV62175646; called by muse, mutect2, varscan2
- OGFOD2 | c.325T>C p.F109L (on ENST00000228922 / NM_001304833.1; = p.F49L on NM_024623.3) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs373328961; called by muse, mutect2, varscan2
- OR10S1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs957629824; called by muse, mutect2
- PBRM1 | c.2647G>T p.G883* | Nonsense Mutation (SNP) | VAF 56/172 reads (33%) | catalogued as COSV56284859, COSV56298440; called by muse, mutect2, varscan2
- PIGR | c.388+1del p.X130_splice | Splice Site (DEL) | VAF 24/74 reads (32%) | catalogued as COSV62904046; called by mutect2, pindel, varscan2
- PLXNA4 | c.4904G>A p.R1635H | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs754615235, COSV58137527; called by muse, mutect2, varscan2
- PTPRF | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1453259016; called by muse, mutect2, varscan2
- SACS | c.9284del p.P3095Lfs*8 | Frame Shift Del (DEL) | VAF 88/292 reads (30%) | catalogued as rs1463970507; called by mutect2, pindel, varscan2
- SERPINB4 | c.347del p.L116Yfs*5 | Frame Shift Del (DEL) | VAF 78/262 reads (30%) | catalogued as COSV61984201; called by mutect2, varscan2
- SLC9A3R1 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs754888522, COSV52854828; called by muse, mutect2, varscan2
- TET3 | c.2866C>T p.R956W | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352306619; called by muse, mutect2, varscan2
- VHL | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553619440, CD941807, CM951279, CM995307, COSV56548602, COSV56556234, COSV56560242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSS2 | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADGB | c.4154A>C p.D1385A | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- AFAP1 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ARHGDIG | c.237_238del p.L80Afs*50 | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- C8orf82 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FAM122A | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXL17 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GLS | c.1537A>G p.K513E | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- GPR151 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- HSPA8 | c.1112A>G p.Y371C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- IGSF9B | c.3309G>C p.W1103C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRCOL1 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 44/113 reads (39%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MEGF6 | c.2197G>T p.V733L | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO1A | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOD2 | c.2083A>G p.T695A | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTRK1 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 58/377 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10S1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2
- PCNT | c.6677C>G p.S2226C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PEX1 | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIGG | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKD1L3 | c.3651G>T p.M1217I | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, varscan2
- PPP1R3G | c.479T>A p.V160E | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- RBM33 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- RPSA | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 55/328 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, varscan2
- SEC16A | c.4894-1G>T p.X1632_splice | Splice Site (SNP) | VAF 56/163 reads (34%) | called by muse, mutect2, varscan2
- SOCS4 | c.1154T>C p.F385S | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- STK32C | c.985C>A p.L329M | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- UBR4 | c.9034G>A p.G3012R | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC80 | c.5563G>T p.V1855F | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZC3H11A | c.865T>A p.F289I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF44 | c.467A>C p.N156T (on ENST00000356109 / NM_001164276.2; = p.N108T on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF736 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADAMTS2 | c.345C>A p.V115= | Silent (SNP) | VAF 101/331 reads (31%) | called by muse, mutect2, varscan2
- ALDH3B1 | c.492T>C p.A164= | Silent (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- ATR | c.7704A>G p.P2568= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as COSV63391720; called by muse, mutect2, varscan2
- DYRK2 | c.852C>T p.V284= (on ENST00000344096 / NM_006482.3; = p.V211= on NM_003583.4) | Silent (SNP) | VAF 51/186 reads (27%) | called by muse, mutect2, varscan2
- EEFSEC | c.570A>G p.G190= | Silent (SNP) | VAF 58/157 reads (37%) | called by muse, mutect2, varscan2
- EPHA5 | c.2226G>A p.V742= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV56655405, COSV99899617; called by muse, mutect2, varscan2
- NPTXR | c.930G>A p.R310= | Silent (SNP) | VAF 47/176 reads (27%) | called by muse, mutect2, varscan2
- PRKX | c.501G>A p.E167= | Silent (SNP) | VAF 103/168 reads (61%) | catalogued as rs1459626985; called by muse, mutect2, varscan2
- RSF1 | c.1665T>C p.A555= | Silent (SNP) | VAF 37/167 reads (22%) | called by muse, mutect2, varscan2
- SEC16A | c.5655G>C p.R1885= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99259739; called by muse, mutect2
- TENM2 | c.4677T>C p.I1559= (on ENST00000518659 / NM_001122679.2; = p.I1320= on NM_001080428.3) | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- VAV3 | c.2277T>C p.D759= | Silent (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-3759A>G | Intron (SNP) | VAF 69/226 reads (31%) | called by muse, mutect2, varscan2
- EIF4G1 | c.61-35T>C | Intron (SNP) | VAF 75/221 reads (34%) | called by muse, mutect2, varscan2
- EIF4G1 | c.61-34C>T | Intron (SNP) | VAF 76/226 reads (34%) | catalogued as COSV100072288; called by muse, mutect2, varscan2
- GAMT | c.570+19C>T | Intron (SNP) | VAF 65/201 reads (32%) | called by muse, mutect2, varscan2
- LPCAT2 | c.853-3835C>G | Intron (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- MUC20P1 | n.559C>A | RNA (SNP) | VAF 183/1505 reads (12%) | called by muse, varscan2
- SPOUT1 | c.*11G>C | 3'UTR (SNP) | VAF 66/254 reads (26%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4905T>A | Intron (SNP) | VAF 155/257 reads (60%) | called by muse, mutect2, varscan2
